Somatic mutation profile of tumor specimen TCGA-C5-A1M7-01A (aliquot TCGA-C5-A1M7-01A-11D-A13W-08) from TCGA case TCGA-C5-A1M7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 37.8 years (13,808 days).
Specimen TCGA-C5-A1M7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0191eed-c8d5-40dd-8245-75bee9219041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1M7-10A (Blood Derived Normal), aliquot TCGA-C5-A1M7-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba5d313c-edfd-43c2-a368-7ecb51bfbd21

The open-access MAF lists 131 somatic variants for this specimen: 93 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 35, Nonsense Mutation 8, Splice Region 3, 5'Flank 2, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61250264; called by muse, mutect2, varscan2
- ACOT12 | c.1518C>T p.I506= | Splice Region (SNP) | VAF 13/103 reads (13%) | catalogued as rs746317652, COSV56894980; called by muse, mutect2, varscan2
- ADGRB1 | c.4049C>T p.T1350M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs772612293, COSV60103302; called by muse, mutect2, varscan2
- ALAS2 | c.1585A>T p.M529L | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as COSV100238465; called by muse, mutect2
- ALG6 | c.1507C>G p.Q503E | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV54643856; called by muse, mutect2, varscan2
- ASAP1 | c.3034C>G p.Q1012E | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100727470; called by muse, mutect2, varscan2
- BEST3 | c.1963G>C p.D655H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV58301472; called by muse, mutect2, varscan2
- C2CD2L | c.1386A>G p.L462= | Splice Region (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100371331; called by muse, mutect2
- CEND1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs149620345; called by mutect2, varscan2
- CFP | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99901575; called by muse, mutect2, varscan2
- COL15A1 | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770341356; called by muse, mutect2, varscan2
- CPSF1 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs781963457, COSV62941822; called by muse, mutect2, varscan2
- DHRS12 | c.645G>A p.W215* (on ENST00000444610 / NM_001377930.1; = p.W166* on NM_024705.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as rs1465429120; called by muse, mutect2, varscan2
- DNAH5 | c.3905T>A p.L1302Q | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CD065703; called by muse, mutect2, varscan2
- ENAH | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs549324711, COSV52866719; called by muse, mutect2, varscan2
- ETHE1 | c.228G>T p.V76= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV52677362; called by muse, mutect2
- FAIM | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV58159076; called by muse, mutect2, varscan2
- FBXO42 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.028); catalogued as rs1400400273; called by muse, varscan2
- FBXW9 | c.612C>G p.I204M (on ENST00000587955; = p.I214M on NM_032301.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100790381, COSV63509837; called by muse, varscan2
- FEM1C | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV99174390; called by muse, mutect2
- FLCN | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV99550534; called by muse, mutect2
- FLG | c.10804C>G p.H3602D | Missense Mutation (SNP) | VAF 25/723 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV100911727; called by muse, mutect2
- FNDC1 | c.3790C>T p.R1264C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs370423767, COSV99794936; called by muse, varscan2
- GPATCH3 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1375525101, COSV100658886; called by muse, mutect2, varscan2
- H2BW1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs372943452, COSV54221050; called by muse, mutect2, varscan2
- HLCS | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV60795427; called by muse, mutect2
- HNRNPLL | c.803-1G>A p.X268_splice | Splice Site (SNP) | VAF 8/73 reads (11%) | catalogued as COSV55369613, COSV99696606; called by muse, mutect2
- IGLV1-47 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs542520350; called by muse, mutect2, varscan2
- IRAG1 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70212565; called by muse, mutect2, varscan2
- IRAK1BP1 | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100884897; called by muse, mutect2
- ISL1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57934186; called by muse, mutect2, varscan2
- ITIH5 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs749743981, COSV53669740; called by muse, mutect2, varscan2
- JRKL | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV99567414; called by muse, mutect2
- KDM4C | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV101184957; called by muse, mutect2
- LINGO1 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as rs912928791, COSV62438468; called by muse, mutect2
- LRRC40 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1344899504; called by muse, mutect2, varscan2
- LRRIQ1 | c.1986T>G p.D662E | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV101280625; called by muse, mutect2
- MDM1 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs749142526, COSV57444191; called by muse, varscan2
- MED17 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99316102; called by muse, mutect2
- OR2T6 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV63216226; called by muse, mutect2, varscan2
- PTPRN2 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs372551467; called by mutect2, varscan2
- RNF220 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs377270177; called by muse, mutect2, varscan2
- SEMA6D | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100317222; called by muse, mutect2
- SENP5 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052109, COSV60207799; called by muse, mutect2
- SLC27A2 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755222778, COSV51058622; called by muse, mutect2
- TRIM46 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.259); catalogued as rs1444724249; called by muse, mutect2
- USP53 | c.1917G>A p.M639I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1052997784; called by muse, mutect2, varscan2
- XKR3 | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV58885422, COSV58885941; called by muse, mutect2, varscan2
- AIM2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- AKNAD1 | c.926C>G p.S309* | Nonsense Mutation (SNP) | VAF 107/406 reads (26%) | called by muse, mutect2, varscan2
- ANK3 | c.4985C>G p.S1662* | Nonsense Mutation (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- ANKRD30A | c.1258G>C p.E420Q (on ENST00000611781; = p.E364Q on NM_052997.2) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ANKRD44 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- BRPF1 | c.2007C>G p.I669M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BRS3 | c.33G>C p.Q11H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- C6orf118 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDK12 | c.1678C>T p.L560F | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DENND2C | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- DLG2 | c.1146C>G p.Y382* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2
- DOCK7 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRG1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- DTX3L | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- DYNC1H1 | c.13552G>A p.E4518K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENO1 | c.1081dup p.Q361Pfs*17 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- EPG5 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO42 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, varscan2
- FLG | c.1307C>G p.S436* | Nonsense Mutation (SNP) | VAF 51/335 reads (15%) | called by muse, mutect2, varscan2
- GPR155 | c.1296G>C p.W432C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- H2AX | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); called by muse, mutect2
- HERC2 | c.1141C>G p.Q381E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HOXA4 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IL18RAP | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | called by muse, varscan2
- KIF17 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- MAGEC3 | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 41/258 reads (16%) | called by muse, mutect2, varscan2
- MED12 | c.3328T>C p.F1110L | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NLRP9 | c.1726_1727del p.E576Tfs*29 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- PCDHB15 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- PHC2 | c.2312T>G p.L771R (on ENST00000257118 / NM_198040.2; = p.L236R on NM_004427.4) | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PHIP | c.5254G>A p.E1752K | Missense Mutation (SNP) | VAF 347/1193 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLM | c.267_284del p.A90_T95del | In Frame Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- PRELP | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RBM5 | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SEMA5A | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.6907C>T p.P2303S | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SH3GL1 | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SNU13 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.186); called by muse, mutect2
- TBL1XR1 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- TMEM60 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- TPRN | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUT1 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- WWP2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF568 | c.1091G>A p.C364Y | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF592 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ABCC1 | c.2373C>T p.F791= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as rs748257791, COSV100579890; called by muse, mutect2, varscan2
- ACKR4 | c.666C>T p.I222= | Silent (SNP) | VAF 48/157 reads (31%) | called by muse, mutect2, varscan2
- ACR | c.777C>T p.I259= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- ARHGDIA | c.312G>T p.L104= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV53907660; called by muse, mutect2, varscan2
- ARMCX2 | c.930C>A p.G310= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as COSV57529587; called by muse, mutect2, varscan2
- ASB4 | c.501C>T p.N167= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.426G>A p.V142= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs760470009; called by muse, mutect2, varscan2
- BAIAP2 | c.627G>A p.A209= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs746438078, COSV100348127; called by muse, mutect2, varscan2
- CAMK2G | c.483C>T p.A161= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as rs756831952; called by muse, mutect2, varscan2
- CHST1 | c.906C>T p.Y302= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- COCH | c.1722G>C p.L574= (on ENST00000216361 / NM_001347720.1; = p.L509= on NM_004086.3) | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV53549575; called by muse, mutect2, varscan2
- CRTC2 | c.2081G>A p.*694= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- GTPBP2 | c.1185C>T p.L395= | Silent (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- HHIPL2 | c.1549C>T p.L517= | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- HOXA4 | c.60C>T p.F20= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs893637605; called by muse, mutect2, varscan2
- HTR1A | c.708C>T p.T236= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs199801230, COSV100109162; called by muse, mutect2, varscan2
- KCNH7 | c.58C>A p.R20= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1399458262, COSV59800205; called by muse, mutect2
- LTK | c.1743C>T p.L581= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- MCF2L | c.1272C>T p.Y424= (on ENST00000375608; = p.Y392= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs370980984; called by muse, mutect2, varscan2
- MROH8 | c.1200C>G p.L400= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99457527; called by muse, mutect2, varscan2
- NABP2 | c.51G>A p.L17= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV57212571, COSV57212775; called by muse, mutect2, varscan2
- NRP2 | c.2355C>A p.A785= | Silent (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- NTMT1 | c.552C>T p.C184= | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- PHF11 | c.612G>A p.V204= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.54G>A p.L18= | Silent (SNP) | VAF 40/356 reads (11%) | called by muse, mutect2, varscan2
- R3HDM2 | c.1101C>T p.G367= | Silent (SNP) | VAF 26/210 reads (12%) | catalogued as rs139077619; called by muse, mutect2, varscan2
- REG4 | c.213G>A p.L71= | Silent (SNP) | VAF 76/257 reads (30%) | called by muse, mutect2, varscan2
- RUFY3 | c.42C>T p.T14= | Silent (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- SLC12A5 | c.615C>T p.L205= (on ENST00000454036 / NM_001134771.2; = p.L182= on NM_020708.5) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV54798428; called by muse, mutect2, varscan2
- SLC25A44 | c.633C>T p.L211= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- SLC45A1 | c.1956C>A p.L652= | Silent (SNP) | VAF 36/294 reads (12%) | called by muse, varscan2
- SVIL | c.5436C>G p.V1812= (on ENST00000355867 / NM_021738.3; = p.V1386= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100881168; called by muse, mutect2, varscan2
- THSD1 | c.1872G>A p.L624= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- TMC6 | c.1032C>G p.L344= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, varscan2
- TRRAP | c.8361G>A p.E2787= (on ENST00000359863 / NM_001244580.1; = p.E2769= on NM_003496.3) | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100722653; called by muse, mutect2, varscan2
- MCF2 | chrX:139646825 A>G | 5'Flank (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- TPM3 | chr1:154193677 G>C | 5'Flank (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2510G>A | Intron (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
